Somatic mutation profile of tumor specimen 0DOXGY from CCDI case PBCDAC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.6 years (6,069 days).
Specimen 0DOXGY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 941b5643-c178-436d-b0d3-e99674ef565a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOXG4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76bb1088-c3f4-4484-9796-dc4e52c43d98

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Splice Region 3, Intron 2, 5'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 83/167 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV64733062; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 372/390 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ARHGEF5 | c.4025C>T p.T1342M | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs768010897; called by muse, varscan2
- ASPM | c.4591C>T p.R1531C | Missense Mutation (SNP) | VAF 173/280 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs780484121, COSV54139402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 143/225 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374558503, COSV61984948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNQ | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as rs918989098, COSV52344771; called by muse, mutect2, varscan2
- CDON | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs559379897; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM160A1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 298/390 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs542161062, COSV68663977; called by muse, mutect2, varscan2
- FBH1 | c.1516G>A p.V506I (on ENST00000362091 / NM_178150.3; = p.V557I on NM_032807.4) | Missense Mutation (SNP) | VAF 170/371 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1391716724; called by muse, mutect2, varscan2
- GAB1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 191/274 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377700737; called by muse, mutect2, varscan2
- IFNGR2 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 114/180 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51641371; called by muse, mutect2, varscan2
- IGF2BP2 | c.1071C>T p.N357= | Splice Region (SNP) | VAF 145/435 reads (33%) | catalogued as rs773362377; called by muse, mutect2, varscan2
- PCSK5 | c.4865C>T p.P1622L | Missense Mutation (SNP) | VAF 133/337 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1472310430; called by muse, mutect2, varscan2
- PDGFRA | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 324/438 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57275957; called by muse, mutect2, varscan2
- PDGFRA | c.937G>C p.G313R | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57273098, COSV57275974; called by muse, mutect2
- PRKCH | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 121/436 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs375617319; called by muse, mutect2, varscan2
- PROX1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV54776614; called by muse, mutect2, varscan2
- RNF183 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 193/404 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as rs746389012; called by muse, mutect2, varscan2
- VWF | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs201015235; called by muse, mutect2, varscan2
- ALDH1L1 | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ATRX | c.4809+2dup | Splice Region (INS) | VAF 92/179 reads (51%) | called by mutect2, varscan2
- BCL11B | c.684G>T p.Q228H (on ENST00000357195 / NM_001282237.2; = p.Q157H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/1531 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- EXOC6B | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 90/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- FBN1 | c.1839C>T p.D613= | Splice Region (SNP) | VAF 123/225 reads (55%) | called by muse, mutect2, varscan2
- FBXL7 | c.1293G>C p.K431N | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- HTRA1 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- LGALS9 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 286/652 reads (44%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAPKBP1 | c.2438C>G p.A813G (on ENST00000456763 / NM_001128608.2; = p.A807G on NM_014994.3) | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NCOR1 | c.6620C>T p.S2207L | Missense Mutation (SNP) | VAF 103/469 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- NONO | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- NOTCH2 | c.5087G>A p.G1696E | Missense Mutation (SNP) | VAF 21/566 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2
- PCDH15 | c.2222C>A p.A741E | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHYKPL | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 124/232 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POLRMT | c.396_397dup p.Q133Pfs*9 | Frame Shift Ins (INS) | VAF 95/172 reads (55%) | called by mutect2, varscan2
- PRDM14 | c.258G>C p.R86S | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAF1 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SDHA | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TAF1L | c.1661T>C p.L554P | Missense Mutation (SNP) | VAF 249/501 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUBAL3 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- UNC79 | c.1296C>G p.I432M (on ENST00000393151 / NM_001346218.2; = p.I255M on NM_020818.5) | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF576 | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 85/115 reads (74%) | SIFT tolerated (0.32); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- CRIM1 | c.609C>T p.C203= | Silent (SNP) | VAF 103/194 reads (53%) | called by muse, mutect2, varscan2
- FURIN | c.2346C>T p.G782= | Silent (SNP) | VAF 51/227 reads (22%) | catalogued as rs571395407; called by muse, mutect2, varscan2
- IFT172 | c.4437T>C p.N1479= | Silent (SNP) | VAF 93/326 reads (29%) | called by muse, mutect2, varscan2
- MAP3K15 | c.1710C>T p.H570= | Silent (SNP) | VAF 59/145 reads (41%) | catalogued as rs369231619; called by muse, mutect2, varscan2
- MSLN | c.738C>T p.D246= | Silent (SNP) | VAF 113/163 reads (69%) | catalogued as rs754476044, COSV53500731; called by muse, mutect2, varscan2
- OR2G2 | c.678C>T p.H226= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as rs779772045, COSV60740879; called by muse, mutect2, varscan2
- PPP1R3A | c.1989A>T p.G663= | Silent (SNP) | VAF 75/279 reads (27%) | catalogued as COSV52894088; called by muse, mutect2, varscan2
- SDR42E1 | c.672C>T p.H224= | Silent (SNP) | VAF 180/188 reads (96%) | catalogued as rs762426199, COSV61094977; called by muse, mutect2, varscan2
- TUBAL3 | c.1335T>C p.S445= | Silent (SNP) | VAF 76/483 reads (16%) | called by muse, mutect2, varscan2
- ZNF282 | c.1533C>T p.H511= | Silent (SNP) | VAF 67/158 reads (42%) | catalogued as rs1464805398; called by muse, mutect2, varscan2
- GABBR2 | c.322-28881C>T | Intron (SNP) | VAF 223/449 reads (50%) | catalogued as rs530868732; called by muse, mutect2, varscan2
- LTBP4 | c.2633-11G>A | Intron (SNP) | VAF 10/49 reads (20%) | catalogued as rs1229025015; called by muse, varscan2
- MUC19 | n.5762T>C | RNA (SNP) | VAF 180/291 reads (62%) | called by muse, mutect2, varscan2
- PGR | c.-32A>G | 5'UTR (SNP) | VAF 35/134 reads (26%) | called by muse, mutect2, varscan2
